CCDI case PBBZJN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5174b0a7-ceb7-4d7d-8f52-25a9bfb70141

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 13.7 years (5,005 days).

Biospecimens (3 samples)
- Sample 0DLSX0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLSX6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLSXU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
